Surgical pathology report (de-identified scan), TCGA case TCGA-YT-A95E, project TCGA-THYM (Thymoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YT-A95E-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Anterior mediastinum

“Tumor of the anterior mediastinum”

- B2 Thymoma, measuring 9.0 x 8.7 x 6.5cm;
- Surgical margins uninvolved by neoplasia.

ICD C3

Thymoma, type B2 NOS
8584/1

Site Anterior mediastinum
C381

W 3/13/14

Source: NCI Genomic Data Commons file 3c96d836-41bb-48fc-98f2-2c76320aeafa (TCGA-YT-A95E.65F396D8-0059-420B-8F48-BA0294D5F8C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).